MMRF case MMRF_2490 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1a014df7-5b60-45f7-9194-3cc53c40ca28

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Dead; Days to death: 349 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.4 years (29,723 days); ISS stage: III; Days to last known disease status: 349 days; Days to last follow up: 349 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 54 days; Days to treatment end: 82 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 91 days; Days to treatment end: 146 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 161 days; Days to treatment end: 343 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 161 days; Days to treatment end: 223 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 349.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 2): M Protein 5.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.811 mg/dL; Immunoglobulin G 4.51 g/L; Immunoglobulin A 39.8 g/L; Immunoglobulin M 0.79 g/L; Beta 2 Microglobulin 13.7 µg/mL; Lactate Dehydrogenase 7.02 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 10.9 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 311 ×10⁹/L; Creatinine 145 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.68 mmol/L; Albumin 31 g/L; Total Protein 10.8 g/dL; Glucose 11 mmol/L; C-Reactive Protein 0.11 mg/dL.
- Day 91 (ECOG 0): M Protein 4.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.629 mg/dL; Immunoglobulin G 3.02 g/L; Immunoglobulin A 31.5 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 13.8 µg/mL; Lactate Dehydrogenase 6.58 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 30 g/L; Total Protein 9.6 g/dL; Glucose 8.75 mmol/L.
- Day 182 (ECOG 1): M Protein 2.82 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.136 mg/dL; Immunoglobulin G 1.63 g/L; Immunoglobulin A 24 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 8.66 µg/mL; Lactate Dehydrogenase 10.1 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.23 mmol/L; Albumin 31 g/L; Total Protein 8.2 g/dL; Glucose 11.1 mmol/L.
- Day 266 (ECOG 0): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.626 mg/dL; Immunoglobulin G 3.25 g/L; Immunoglobulin A 3.43 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 5.93 µg/mL; Lactate Dehydrogenase 4.88 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 324 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 7.43 mmol/L.

Other clinical attributes
- Day -1: Weight: 80 kg; Height: 166 cm.

Biospecimens (3 samples)
- Sample MMRF_2490_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2490_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
- Sample MMRF_2490_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 91 days.
